Somatic mutation profile of tumor specimen TARGET-30-PAKVUY-01A (aliquot TARGET-30-PAKVUY-01A-01D) from TARGET case TARGET-30-PAKVUY, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 4.1 years (1,482 days).
Specimen TARGET-30-PAKVUY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a427c5b6-854c-4d40-8143-1238d662da2c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PAKVUY-10A (Blood Derived Normal), aliquot TARGET-30-PAKVUY-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c8c5086a-301f-4e12-9106-dac05ab77415

The open-access MAF lists 6 somatic variants for this specimen: 2 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 3, Nonsense Mutation 1, RNA 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LRRC7 | c.835A>T p.R279* (on ENST00000651989 / NM_001370785.2; = p.R246* on NM_001330635.3 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 4/29 reads (14%) | catalogued as COSV50457315; called by muse, mutect2, varscan2
- MUC16 | c.12974G>T p.S4325I | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.019); catalogued as COSV67465710; called by muse, mutect2, varscan2
- ADAM29 | c.1960C>T p.L654= | Silent (SNP) | VAF 7/69 reads (10%) | called by muse, mutect2
- MYH7 | c.2235G>T p.L745= | Silent (SNP) | VAF 9/102 reads (9%) | called by muse, mutect2
- WDR4 | c.24G>A p.A8= | Silent (SNP) | VAF 29/123 reads (24%) | catalogued as COSV57733512; called by muse, mutect2, varscan2
- TUBB7P | n.874C>A | RNA (SNP) | VAF 8/134 reads (6%) | catalogued as rs781876438; called by muse, mutect2
